Somatic mutation profile of tumor specimen 0DQU4Z from CCDI case PBCFES, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.8 years (4,670 days).
Specimen 0DQU4Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a21b844-324f-4ebb-aefa-570888cd0636.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQU59 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f35a2a71-259d-404e-9480-3a48326e7ad2

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDH9 | c.2639C>G p.S880C | Missense Mutation (SNP) | VAF 48/854 reads (6%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.942); catalogued as COSV60582216; called by muse, mutect2
- POLG | c.1251-38G>A | Intron (SNP) | VAF 17/333 reads (5%) | called by muse, mutect2
- ZSCAN32 | chr16:3382945 C>G | 3'Flank (SNP) | VAF 21/660 reads (3%) | called by muse, mutect2
